Somatic mutation profile of tumor specimen TCGA-BP-5001-01A (aliquot TCGA-BP-5001-01A-01D-1462-08) from TCGA case TCGA-BP-5001, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 43.4 years (15,858 days).
Specimen TCGA-BP-5001-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca6fd286-0768-4c99-9b76-bbd85820a4c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5001-11A (Solid Tissue Normal), aliquot TCGA-BP-5001-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18377811-c04a-40f5-90f5-7e0cf291d71d

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Splice Site 2, Frame Shift Del 2, Splice Region 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAD | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs142146358; called by muse, varscan2
- CHD4 | c.2834T>A p.L945H (on ENST00000357008 / NM_001363606.2; = p.L958H on NM_001273.5) | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100539541, COSV58894775; called by muse, mutect2, varscan2
- DDX50 | c.1555A>G p.T519A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65291704; called by muse, mutect2, varscan2
- EIF4G3 | c.4685G>A p.G1562D | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51673966, COSV51687877; called by muse, mutect2, varscan2
- EMSY | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV58257327; called by muse, mutect2, varscan2
- FCRL5 | c.2180G>A p.C727Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62511428; called by muse, mutect2, varscan2
- GAS2L3 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57156086; called by muse, mutect2, varscan2
- GCN1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs1319481654, COSV56103748; called by muse, mutect2, varscan2
- GID8 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV56610920; called by muse, mutect2, varscan2
- GUCY1B1 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52373640; called by muse, mutect2, varscan2
- IL1RL1 | c.447+2T>G p.X149_splice | Splice Site (SNP) | VAF 17/65 reads (26%) | catalogued as COSV52112071; called by muse, mutect2, varscan2
- KCNH7 | c.2102A>C p.E701A | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV59784916; called by muse, mutect2, varscan2
- LAMA4 | c.504-1G>C p.X168_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as COSV57891971, COSV57903937; called by muse, mutect2, varscan2
- MTOR | c.4298T>C p.L1433S | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63868399; called by muse, mutect2, varscan2
- MYNN | c.1511G>T p.C504F | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62990936; called by muse, mutect2, varscan2
- PCBP2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV63727930; called by muse, mutect2, varscan2
- PCDHGA2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV53898302; called by muse, mutect2, varscan2
- PLEKHG2 | c.4099A>G p.T1367A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV52678323; called by muse, mutect2, varscan2
- SATB2 | c.1176A>T p.G392= | Splice Region (SNP) | VAF 12/48 reads (25%) | catalogued as rs1374626385, COSV53478045; called by muse, varscan2
- SH3BP2 | c.1403A>G p.E468G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV62553533; called by muse, mutect2, varscan2
- SLC7A2 | c.178G>A p.A60T (on ENST00000494857 / NM_001370338.1; = p.A100T on NM_003046.6) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50247589; called by muse, mutect2
- SPTA1 | c.7134G>T p.Q2378H | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as CS046130, COSV100934908, COSV63748912; called by muse, mutect2, varscan2
- TRADD | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV50757610; called by muse, mutect2, varscan2
- VWA2 | c.1000C>A p.L334M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV53904943; called by muse, mutect2
- WASHC5 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs369756799; called by muse, mutect2, varscan2
- MIDEAS | c.1686_1693del p.K562Nfs*78 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel*, varscan2*
- PPP2R3A | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2
- ST18 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); called by muse, mutect2
- WAC | c.477del p.K159Nfs*33 | Frame Shift Del (DEL) | VAF 43/166 reads (26%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.660G>T p.L220= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as COSV61464173; called by muse, mutect2, varscan2
- DNAH11 | c.2775C>T p.H925= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1173313331, COSV60939732; called by muse, mutect2
- FLRT2 | c.984C>T p.I328= | Silent (SNP) | VAF 81/306 reads (26%) | catalogued as rs765427436, COSV58136224; called by muse, mutect2, varscan2
- LSM8 | c.207C>G p.V69= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as COSV50800384; called by muse, mutect2
- PLEKHH2 | c.3642A>T p.T1214= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV56749682; called by muse, mutect2, varscan2
- PTCH1 | c.4152G>C p.P1384= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV59462850; called by muse, mutect2, varscan2
- RNF113A | c.822C>T p.V274= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV65097073; called by muse, mutect2, varscan2
- SDCCAG8 | c.1762T>C p.L588= | Silent (SNP) | VAF 45/206 reads (22%) | catalogued as COSV59404697; called by muse, mutect2, varscan2
- SKI | c.1194G>A p.P398= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs374138016; called by muse, varscan2
- SLCO1A2 | c.606A>T p.G202= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV56597284; called by muse, mutect2, varscan2
- GPR35 | c.-488G>A | 5'UTR (SNP) | VAF 102/522 reads (20%) | catalogued as rs373072755; called by muse, varscan2
